Gene-level copy-number profile of tumor specimen C3L-03467-01 from CPTAC case C3L-03467, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 73.3 years (26,781 days).
Specimen C3L-03467-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4e3dbe7-a015-4912-82b5-7e5a2c2eefe2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03467-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/627849b6-7cbc-4593-8b7d-0b26529b8287

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,917; copy number 2: 11,275; copy number 3: 25,318; copy number 4: 14,477; copy number 5: 3,191; copy number 6: 1,146; copy number 7: 548; copy number 8: 93; copy number 9: 56; copy number 10: 148; copy number 11: 9; copy number 13: 5; copy number 14: 44; copy number 15: 5; copy number 16: 2; copy number 17: 28; copy number 18: 33; copy number 19: 5; copy number 21: 10; copy number 22: 21; copy number 24: 11; copy number 28: 26; copy number 30: 8; copy number 33: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,056 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,726,252–154,379,273, 46 genes, copy number 8: Y_RNA, INTS3, AL513523.4, AL513523.3, SLC27A3, Y_RNA, GATAD2B, AL513523.2, AL513523.1, AL831737.1, AL358472.5, DENND4B, CRTC2, SLC39A1, AL358472.7, MIR6737, AL358472.4, AL358472.3, CREB3L4, JTB, AL358472.6, AL358472.2, RAB13, RPS27, NUP210L, AL358472.1, RNU6-179P, RPS7P2, MIR5698, TPM3, RN7SL431P, MIR190B, C1orf189, C1orf43, UBAP2L, SNORA58B, HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17.
- chr1:154,697,455–157,898,256, 153 genes, copy number 7 (broad region; genes not listed).
- chr2:108,322,238–108,687,246, 7 genes, copy number 7 (within-gene range 4–7): SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2, GCC2-AS1, LIMS1.
- chr2:109,129,205–109,504,634, 1 gene, copy number 7 (within-gene range 4–7): SH3RF3.
- chr2:109,313,571–111,699,033, 62 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:134,119,983–134,454,621, 4 genes, copy number 7: MGAT5, MIR3679, RNA5SP104, EDDM3CP.
- chr2:136,765,545–140,221,485, 30 genes, copy number 8–11: THSD7B, RNA5SP105, Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr4:46,993,723–48,780,322, 25 genes, copy number 7–10 (within-gene range 3–10): GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P.
- chr4:53,377,641–56,524,959, 68 genes, copy number 7–9 (broad region; genes not listed).
- chr8:31,497,423–31,598,204, 2 genes, copy number 8: AC068672.1, RNA5SP261.
- chr10:73,995,193–81,137,335, 145 genes, copy number 10–33 (within-gene range 10–39) (broad region; genes not listed).
- chr10:82,224,213–82,232,920, 2 genes, copy number 10 (within-gene range 4–10): AC010157.1, NRG3-AS1.
- chr15:27,754,875–28,099,315, 3 genes, copy number 7: OCA2, AC090696.1, RPL5P32.
- chr15:34,379,068–34,850,395, 17 genes, copy number 7–11: GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1, LINC02252, GJD2, AC087457.1, ACTC1, TUBAP11.
- chr16:24,472,798–26,137,685, 31 genes, copy number 10: AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16.
- chr16:27,268,205–27,549,913, 6 genes, copy number 9 (within-gene range 6–9): NSMCE1-DT, AC106739.1, IL4R, IL21R, IL21R-AS1, GTF3C1.
- chr18:7,231,125–15,330,282, 220 genes, copy number 7 (broad region; genes not listed).
- chr18:65,105,873–67,137,751, 12 genes, copy number 7–8: AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9.
- chr19:27,638,483–32,405,560, 82 genes, copy number 8–19 (within-gene range 4–19) (broad region; genes not listed).
- chr22:18,029,385–18,757,906, 31 genes, copy number 7: LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18, FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.
- chr22:18,906,028–18,947,741, 4 genes, copy number 7–8: DGCR6, AC007326.4, PRODH, AC007326.5.
- chr22:28,742,039–30,505,711, 77 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr22:31,281,594–31,970,400, 27 genes, copy number 7: PIK3IP1, PIK3IP1-DT, RNA5SP496, PATZ1, LINC01521, RNU6-338P, DRG1, EIF4ENIF1, AL096701.3, RNU6-28P, SFI1, AL096701.4, H2AZP6, AL096701.2, AL096701.1, PISD, MIR7109, PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1.
- chr22:31,981,147–31,981,427, 1 gene, copy number 7: RN7SL305P.

Autosomal genes at a single copy (total copy number 1): 1,882. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
